Somatic mutation profile of tumor specimen TCGA-RB-A7B8-01A (aliquot TCGA-RB-A7B8-01A-12D-A33T-08) from TCGA case TCGA-RB-A7B8, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 81.0 years (29,585 days).
Specimen TCGA-RB-A7B8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2e6a640-f9eb-48d9-80dc-26816557877a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RB-A7B8-10A (Blood Derived Normal), aliquot TCGA-RB-A7B8-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f43aa594-6585-4133-bec3-783da58c1136

The open-access MAF lists 50 somatic variants for this specimen: 31 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 16, Intron 2, Nonsense Mutation 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 16/130 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.3127A>T p.M1043L | Missense Mutation (SNP) | VAF 167/501 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 98/564 reads (17%) | catalogued as rs976402066, COSV101035559; called by muse, mutect2, varscan2
- ALX3 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 120/495 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1053677141, COSV63928593; called by muse, mutect2, varscan2
- ANXA1 | c.404A>T p.D135V | Missense Mutation (SNP) | VAF 147/829 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV57412185, COSV99973868; called by muse, mutect2, varscan2
- ARMCX3 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 40/528 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs903185505, COSV100362209; called by muse, mutect2
- CACNA1E | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 169/948 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1228711500, COSV62412279; called by muse, mutect2, varscan2
- CACNG2 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 76/1592 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100268663; called by muse, mutect2
- CDH2 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 68/426 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs1218458192, COSV99295847; called by muse, mutect2, varscan2
- CKAP2L | c.679T>G p.L227V | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as COSV100198530; called by muse, mutect2
- COL11A1 | c.1363C>A p.P455T | Missense Mutation (SNP) | VAF 79/596 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100615721, COSV62191823; called by muse, mutect2, varscan2
- D2HGDH | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 86/526 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371794611; called by muse, mutect2, varscan2
- EIF4EBP2 | c.185G>C p.R62P | Missense Mutation (SNP) | VAF 68/491 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV64667149; called by muse, mutect2, varscan2
- EPHB4 | c.2738G>A p.G913D | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.856); catalogued as rs1404035679, COSV100639453, COSV62268804; called by muse, mutect2, varscan2
- FLG | c.9775G>A p.E3259K | Missense Mutation (SNP) | VAF 302/2567 reads (12%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.782); catalogued as rs780813233, COSV64238370; called by muse, mutect2, varscan2
- GNAS | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as COSV58328582; called by muse, mutect2, varscan2
- HAS2 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 132/837 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as rs985314101, COSV58264275; called by muse, mutect2, varscan2
- KLHDC8A | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 85/517 reads (16%) | catalogued as rs1000257355, COSV100903799; called by muse, mutect2, varscan2
- MELK | c.1282A>G p.T428A | Missense Mutation (SNP) | VAF 69/417 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99974422; called by muse, mutect2, varscan2
- NFE2L1 | c.2302A>G p.K768E | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV100671450; called by muse, mutect2
- NUP160 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 84/546 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV65853598; called by muse, mutect2, varscan2
- OPA1 | c.1953A>C p.K651N (on ENST00000361510 / NM_130837.3; = p.K596N on NM_015560.3) | Missense Mutation (SNP) | VAF 40/625 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100655232; called by muse, mutect2
- PCDHB11 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 179/1253 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.042); catalogued as rs200787309, COSV61314213; called by muse, mutect2, varscan2
- PGAM5 | c.467C>A p.T156N | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100452968; called by muse, mutect2, varscan2
- PHACTR1 | c.761C>A p.P254Q | Missense Mutation (SNP) | VAF 88/472 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.276); catalogued as COSV100276308; called by muse, mutect2, varscan2
- POSTN | c.2141T>A p.I714N | Missense Mutation (SNP) | VAF 73/510 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.629); catalogued as COSV101123292; called by muse, mutect2, varscan2
- RRAGD | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 66/427 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100784516; called by muse, mutect2, varscan2
- SLC22A23 | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778961106, COSV66677131; called by muse, mutect2, varscan2
- TAS2R38 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 72/642 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs377342463; called by muse, mutect2, varscan2
- ZNF606 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV100071699; called by muse, mutect2, varscan2
- ZNF658 | c.2864del p.V955Dfs*97 | Frame Shift Del (DEL) | VAF 138/1043 reads (13%) | called by mutect2, pindel, varscan2
- ADAMTS20 | c.1230T>C p.G410= | Silent (SNP) | VAF 23/240 reads (10%) | catalogued as COSV101239105; called by muse, mutect2
- ASCC3 | c.4671T>C p.P1557= | Silent (SNP) | VAF 15/410 reads (4%) | catalogued as rs1274646291, COSV100976333; called by muse, mutect2
- CCDC88B | c.3360C>T p.H1120= | Silent (SNP) | VAF 39/295 reads (13%) | catalogued as rs755555956, COSV57265335; called by muse, mutect2, varscan2
- CCDC88C | c.4089C>T p.Y1363= | Silent (SNP) | VAF 165/983 reads (17%) | catalogued as COSV101105414; called by muse, mutect2, varscan2
- DCAF4L1 | c.345C>T p.Y115= | Silent (SNP) | VAF 65/489 reads (13%) | catalogued as rs765518456, COSV60787146; called by muse, mutect2, varscan2
- DENND5B | c.2319G>A p.E773= | Silent (SNP) | VAF 32/670 reads (5%) | catalogued as rs1198677858, COSV100170730; called by muse, mutect2
- GPR78 | c.228C>T p.P76= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as rs1320059794, COSV66763633; called by muse, mutect2
- IGHA1 | c.819C>T p.R273= | Silent (SNP) | VAF 20/436 reads (5%) | catalogued as rs778291607; called by muse, mutect2
- IGHA2 | c.780C>T p.R260= | Silent (SNP) | VAF 23/182 reads (13%) | catalogued as rs782791014; called by muse, mutect2
- ITGA4 | c.1410C>T p.D470= | Silent (SNP) | VAF 58/428 reads (14%) | catalogued as rs183217259, COSV51997793; called by muse, mutect2, varscan2
- JAG1 | c.2931G>A p.E977= | Silent (SNP) | VAF 45/337 reads (13%) | catalogued as rs1379142756, COSV99652631; called by muse, mutect2, varscan2
- MAGEC2 | c.120C>A p.S40= | Silent (SNP) | VAF 58/956 reads (6%) | catalogued as COSV99909484; called by muse, mutect2
- PCDHA12 | c.2202G>A p.P734= | Silent (SNP) | VAF 56/237 reads (24%) | catalogued as COSV56488495, COSV99166277; called by muse, mutect2, varscan2
- SCN3B | c.204C>T p.G68= | Silent (SNP) | VAF 119/674 reads (18%) | catalogued as rs781654457, COSV100173727, COSV54798179; called by muse, mutect2, varscan2
- SLC6A9 | c.849T>C p.F283= (on ENST00000360584 / NM_201649.4; = p.F229= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 156/1053 reads (15%) | catalogued as COSV100746116; called by muse, mutect2, varscan2
- ZBTB38 | c.2109C>T p.A703= | Silent (SNP) | VAF 63/854 reads (7%) | catalogued as rs755447725, COSV100375508; called by muse, mutect2
- AL590867.2 | n.90C>T | RNA (SNP) | VAF 36/716 reads (5%) | catalogued as rs754507115; called by muse, mutect2
- PALM2AKAP2 | c.400+6899G>A | Intron (SNP) | VAF 141/734 reads (19%) | catalogued as rs369150990; called by muse, mutect2, varscan2
- SLC5A9 | c.340-167A>T | Intron (SNP) | VAF 123/1073 reads (11%) | catalogued as COSV99361522; called by muse, mutect2, varscan2
